Gene-level copy-number profile of tumor specimen TARGET-20-PATDNN-04A from TARGET case TARGET-20-PATDNN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,262 days).
Specimen TARGET-20-PATDNN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.b527500b-f8df-5c2a-8386-219a3e8781ff.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PATDNN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate.
https://portal.gdc.cancer.gov/files/0c8985bb-4b1a-4631-a5f6-c5cc53b565db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 159; copy number 1: 2,952; copy number 2: 56,290; copy number 3: 45; copy number 4: 1; copy number 5: 448; copy number 6: 328; copy number 7: 8.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,548,756–248,635,091, 7 genes (within-gene range 0–2): AC098483.1, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr9:60,914,407–61,662,690, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 784 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 2 genes, copy number 5 (within-gene range 2–5): MALLP2, AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr17:60,177,327–83,095,122, 741 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
